Somatic mutation profile of tumor specimen 0DJPCU from CCDI case PBBXHY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 7.3 years (2,679 days).
Specimen 0DJPCU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b0705bd-d91c-4c61-8c62-819f5e4acbdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b975895-193e-408d-bd99-36022ba8a390

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Intron 7, 3'UTR 2, 5'UTR 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 304/521 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- BCHE | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 232/806 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs749068794, COSV52256399; called by muse, mutect2, varscan2
- CCDC9 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs534274243; called by muse, mutect2, varscan2
- CXXC1 | c.1439C>G p.T480R | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV99496390; called by muse, mutect2, varscan2
- FUT1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1445377166; called by muse, mutect2, varscan2
- HECTD1 | c.7367C>T p.T2456M | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs750708787, COSV67947639; called by muse, mutect2, varscan2
- LENG9 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs747099825; called by muse, mutect2, varscan2
- MGA | c.7300C>G p.R2434G (on ENST00000219905 / NM_001164273.1; = p.R2225G on NM_001080541.2) | Missense Mutation (SNP) | VAF 144/620 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54950853; called by muse, mutect2, varscan2
- NLRP3 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 157/700 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60232410; called by muse, mutect2, varscan2
- OR4A47 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV101487077; called by muse, mutect2, varscan2
- PHF21A | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 117/646 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104380913; called by muse, mutect2, varscan2
- TG | c.4562T>C p.L1521P | Missense Mutation (SNP) | VAF 151/1219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55093663; called by muse, mutect2, varscan2
- THSD4 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746459618, COSV99964598, COSV99964600; called by muse, mutect2, varscan2
- BMP3 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CMTR1 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSN2 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 155/528 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- EFCAB12 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 166/674 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- HELB | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP1B | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 110/573 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MRC1 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 102/456 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, varscan2
- MUC17 | c.8021C>A p.P2674H | Missense Mutation (SNP) | VAF 140/518 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MYOM3 | c.1829C>A p.A610D | Missense Mutation (SNP) | VAF 113/570 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NLRX1 | c.1931G>T p.C644F | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHB2 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 114/562 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROB1 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PSMB1 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 153/668 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFMBT2 | c.303dup p.Q102Afs*21 | Frame Shift Ins (INS) | VAF 61/249 reads (24%) | called by mutect2, varscan2
- SPEG | c.4507C>T p.R1503C | Missense Mutation (SNP) | VAF 175/941 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TLN1 | c.6354del p.K2119Rfs*2 | Frame Shift Del (DEL) | VAF 74/344 reads (22%) | called by mutect2, varscan2
- VPS41 | c.1740T>A p.I580= | Splice Region (SNP) | VAF 26/927 reads (3%) | called by muse, mutect2
- ZNF37A | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 159/563 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF385D | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADCY2 | c.861A>C p.T287= | Silent (SNP) | VAF 114/633 reads (18%) | called by muse, mutect2, varscan2
- ADD2 | c.1335G>A p.V445= | Silent (SNP) | VAF 136/724 reads (19%) | called by muse, mutect2, varscan2
- MAP1B | c.6696C>A p.G2232= | Silent (SNP) | VAF 162/917 reads (18%) | called by muse, mutect2, varscan2
- OR10A7 | c.822G>A p.V274= | Silent (SNP) | VAF 117/449 reads (26%) | called by muse, varscan2
- OTOF | c.750G>A p.R250= | Silent (SNP) | VAF 86/435 reads (20%) | catalogued as rs1238190736; called by muse, mutect2, varscan2
- RIN3 | c.1596C>A p.A532= | Silent (SNP) | VAF 89/383 reads (23%) | called by muse, mutect2, varscan2
- UNC5D | c.267C>T p.G89= | Silent (SNP) | VAF 91/918 reads (10%) | catalogued as rs376716411, COSV99776093; called by muse, varscan2
- HNMT | c.137+2541G>T | Intron (SNP) | VAF 173/805 reads (21%) | catalogued as COSV99698616; called by muse, mutect2, varscan2
- INTU | c.-21G>C | 5'UTR (SNP) | VAF 138/383 reads (36%) | called by muse, mutect2, varscan2
- LRRC38 | c.*25A>C | 3'UTR (SNP) | VAF 86/149 reads (58%) | called by muse, mutect2, varscan2
- LRRC63 | c.*79T>G | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/124 reads (10%) | called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- PSG1 | c.1243+355G>C | Intron (SNP) | VAF 107/759 reads (14%) | catalogued as rs1178159056; called by muse, mutect2, varscan2
- TCF4 | c.1637+12G>T | Intron (SNP) | VAF 118/543 reads (22%) | called by muse, mutect2, varscan2
- TCF4 | c.1637+11A>T | Intron (SNP) | VAF 120/546 reads (22%) | catalogued as COSV61902173; called by muse, mutect2, varscan2
- TRMT9B | c.155-71G>T | Intron (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 32/676 reads (5%) | called by muse, mutect2
